Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-5334, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-5334-01A (Primary Tumor).

[page 1 of 3]
Specimen(s) Received

1. Nck: Right neck dissection - level 1A
2. Surgical Waste
3. Soft Tissue: Mental nerve right neck -
4. Soft Tissue: Buccal mucosa, primary tumor, long stitch on lip, short stitch on superior
5. Soft Tissue: Buccal fat
6. Neck: Right neck modified dissection contents
7. Soft Tissue: Inferior alveolar nerve right neck -
8. Soft Tissue: Floor of mouth mucosa (margin)

Diagnosis

1. Right neck; level 1A:
- One lymph node, negative for tumor (0/1).
2. Surgical waste:
- Adipose tissue with no pathologic changes (gross examination only).
3. Mental nerve; right neck:
- Positive for squamous cell carcinoma.
4. Buccal mucosa; excision:
- Squamous cell carcinoma, moderately differentiated.
- a. Maximum tumor dimension 6.0 cm.
- b. Perineural invasion present.
- c. Lymphovascular invasion absent.
- d. Tumor is close (0.2 cm) to infero-anterior soft tissue margin.
- e. Tumor is present at the supero-anterior lip and buccal mucosal margins. All other margins negative for tumor (>0.5 cm).
5. Buccal fat:
- Fibroadipose tissue with chronic inflammation; negative for tumor.
6. Right neck; modified dissection:
- Metastatic squamous cell carcinoma involving six of forty-six lymph nodes (6/46).
- a. Largest involved lymph node measures 3.5 cm.
- b. Involved lymph nodes are in levels IA, IB, II-IV.
- c. Extensive extracapsular extension present.
- Submandibular gland with no pathologic changes (see comment).

[page 2 of 3]
7. Inferior alveolar nerve; right neck:
- Peripheral nerve with no pathologic changes.

8. Floor of mouth mucosa; margin:
- Squamous mucosa, negative for tumor.

Synoptic Data

Specimen Type:	Resection: Buccal
Tumor Site:	Oral Cavity
Histologic Type:	Squamous cell carcinoma, conventional
Tumor Size:	Greatest dimension: 6.0 cm
Histologic Grade:	G2: Moderately differentiated
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L):	Absent
Perineural Invasion:	Present
Margins:	Margin(s) involved by tumor Location(s): supero-anterior buccal and lip mucosal margins
Pathologic Staging (pTNM):	pT3: Tumor or lip or oral cavity more than 4 cm in greatest dimension pN2b: Metastasis in multiple ipsilateral lymph nodes, none more than 6 cm in greatest dimension for all aerodigestive sites except nasopharynx Number of regional lymph nodes examined: 46 Number of regional lymph nodes involved: 6 Extra-capsular extension of nodal tumor: Present pMX: Distant metastasis cannot be assessed

Comment

There is a large cystic mass in level IB that is a metastatic squamous cell carcinoma in a peri-submandibular gland lymph node. There is no invasion of the salivary gland itself.

Gross Description

1. The specimen is labeled with the patient's name and "right neck dissection level 1A". It consists of portion of partly hemorrhagic lymph node measuring 1 x 0.7 x 0.4 cm.
1A bisected and submitted in toto
2. The specimen container labeled with the patient's name and as "surgical waste" consists of a piece of grossly unremarkable fatty tissue measuring 2.2 x 1.8 x 1.3 cm received in 10% buffered formalin.
No tissues submitted for histologic examination.
3. The specimen is labeled with the patient's name and as "mental nerve right neck qs". It consists of a fragment of tissue measuring 0.7 x 0.5 x 0.1 cm. The specimen is submitted in toto for frozen section.
3A frozen section control
4. The specimen container labeled with the patient's name and as "buccal mucosa, primary tumor, long stitch on lip, short stitch on superior" consists of a piece of gray-brown skin, subcutaneous fibrofatty tissue, buccal mucosa with a large tumor and anterior lip mucosa received in 10% buffered formalin. It measures 5.0 cm SI x 3.0 cm ML x 6.5 cm AP. The skin is unremarkable, measures 2.5 cm SI x 5.2 cm AP with a 2.5 cm groove in the AP dimension. The tumor is solid, circumscribed, exophytic and tan with a ragged surface. It measures 5.0 cm SI x 2.0 cm ML x 6.0 cm AP. The margins are painted with silver nitrate. The skin margin is overcoated with green ink. The tumor distance to the margins is as follows: Anterior lip mucosa - right at margin, anterior skin margin - 0.5 cm, anterior buccal mucosal margin - right at

[page 3 of 3]
[REDACTED]

margin, superior buccal mucosa margin - 0.5 cm, superior skin margin -1.2 cm, posterior buccal mucosal margin - 0.5 cm, posterior skin margin -1.0 cm, inferior buccal mucosal margin - 0.5 cm, inferior skin margin - 0.7 cm, infero-anterior buccal mucosal margin - 0.8 cm. Multiple pieces of tumor taken for tissue banking. Photographs are taken of the specimen and downloaded into [REDACTED]. Sections are submitted as follows:

- 4A supero anterior skin, lip mucosa and buccal mucosa margins
- 4B superior skin and buccal mucosa margins
- 4C posterior skin and buccal mucosa margins
- 4D inferior skin and buccal mucosa margin
- 4E infero-anterior buccal mucosa margin
- 4F, 4G tumor, no margins

5. The specimen container labeled with the patient's name and as "buccal fat" consists of two pieces of tissue measuring 0.8 x 0.3 x 0.2 cm and 1 x 0.8 x 0.6 received in 10% buffered formalin. The smaller is a piece of tan-gray soft tissue and the larger a piece of grossly unremarkable fat.

5A submitted in toto

6. The specimen is labeled with the patient's name and "right neck modified dissection contents". It consists of two pieces of an oriented standard neck dissection with overall dimensions of 8.3 x 3 x 1.7 cm and 14 x 7.5 x 4.5 cm. The smaller piece contains level V and the larger piece levels IA, IB, II, III and IV. There is a tumor mass within the levels II and III measuring 4.5 x 1.5 x 1.2 cm. It is tan-gray solid to cystic and abuts the interior jugular vein. The internal jugular vein measures 5 cm in length by 2 cm in diameter and is otherwise unremarkable. The sternocleidomastoid measures 7.5 x 5 x 3 cm. The mass in levels II and III is within the muscle. The submandibular gland measures 3.3 x 3 x 1.8 cm and has a circumscribed soft, necrotic yellowish-tan to pink mass measuring 2.5 x 2.5 x 1.8 cm. Multiple lymph nodes ranging from 0.2 x 0.2 x 0.2 cm to 3.5 x 1.8 x 0.8 cm are identified in multiple levels. Representative sections are submitted.

- 6A level IA multiple lymph nodes
- 6B-6D level IA one lymph node sectioned
- 6E level IB multiple lymph nodes
- 6F level IB one lymph node bisected
- 6G-6I submandibular gland with mass
- 6J, 6K level II solid and cystic mass
- 6L level II multiple lymph nodes
- 6M level II one lymph node bisected
- 6N, 6O level III solid and cystic mass with adjacent interior jugular vein
- 6P level III multiple lymph nodes
- 6Q level III one lymph node bisected
- 6R level III one lymph node trisected
- 6S-6U level IV multiple lymph nodes each block
- 6V-6X level V multiple lymph nodes each block

7. The specimen is labeled with the patient's name and as "inferior alveolar nerve right neck-qs". It consists of a fragment of tissue measuring 0.8 x 0.2 x 0.1 cm. The specimen is submitted in toto for frozen section.

7A frozen section control

8. The specimen is labeled with the patient's name and as "floor of mouth mucosa margin". It consists of a fragment of tan-white tissue measuring 1.2 x 0.4 x 0.2 cm.

[REDACTED]

Quick Section Diagnosis

3. Mental nerve right neck - 3A: Squamous carcinoma present

[REDACTED]

7. Inferior alveolar nerve right neck - 7A: Negative for malignancy

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 1d80c05f-627d-4d6d-bb43-891bd066ec26 (TCGA-CQ-5334.CED69858-ABAD-4493-AA92-2CDF1B11FFB0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).